Surgical pathology report (de-identified scan), TCGA case TCGA-43-7658, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-7658-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Right upper lobe of lung. The entire specimen weighs 142.5 grams.
- B. Lymph node, station 7
- c. Station 9 lymph node

CLINICAL NOTES

--

GROSS DESCRIPTION

A. Received fresh in a single container labelled with the patient's name, medical record number and "right upper lobe" is a single lobe of lung parenchyma that weighs 145.2 grams and measures 16.8 x 7.5 x 2.7 cm. in greatest dimensions. A staple line is present along the medial aspect of the specimen that measures 12.8 cm. in length. The nodule is palpated in the parenchyma that measures 2.1 x 1.7 x 1.8 cm. in greatest dimensions. The pleural surface overlying this nodule is attenuated with some evidence of retraction. The pleural surface overlying this area is inked black. The specimen is sectioned through the tumor. Representative tumor and surrounding normal tissue are submitted for tissue procurement. Additional representative sections are taken through the specimen. The cut surfaces show no additional mass lesions with the exception of the tumor described above. Representative sections were taken for histology according to the block summary: The block summary will be dictated later. Two extra specimens are received.

B. Lymph node, station 7. Received is a single fragment of gray-tan tissue that measures 1.5 cm. in diameter. This specimen is bisected and entirely submitted in block B.

C. Station 9 lymph node. Received fresh in a single container labelled with the patient's name, medical record number and "station 9 lymph node" are multiple fragments of yellow-orange fatty tissue that contain several lymph nodes. These lymph nodes are entirely submitted in blocks C1 and C2.

MICROSCOPIC DESCRIPTION

A. The sections of the mass lesion in the right upper lobe of the lung shows a non-keratinizing poorly differentiated squamous cell carcinoma, as described in the template below:

Histologic type: Non-keratinizing squamous cell carcinoma.

Histologic grade: G3, poorly differentiated.

Primary tumor (pT): pT1; 2.1 x 1.7 x 1.8 cm in greatest dimensions.

Margins of resection: The parenchymal, pleural, and bronchial margins are free of tumor.

Direct extension of tumor: Not identified.

Venous (large vessel) invasion: Not identified.

Arterial (large vessel) invasion: Not identified.

Lymphatic (small vessel) invasion: Not identified.

Regional lymph nodes (pN): pN 0. No tumor is identified in a total of eight (0/8) lymph nodes in parts A, B and C combined.

[page 2 of 2]
[REDACTED]

Distant metastasis (pM): Mx.

Other findings: The tumor is well circumscribed from the surrounding non-neoplastic pulmonary parenchyma and does not involve the overlying pleura at all. Two hilar lymph nodes are identified on the lobectomy specimen. No tumor is seen within the hilar lymph nodes (0/2).

B. A single lymph node is present designated as "station 7". No tumor is seen within this lymph node (0/1).

C. A total of five lymph nodes are identified in the station 9 specimen. No tumor is seen within these five lymph nodes (0/5).

5,3x2

DIAGNOSIS

- A. Lung, right upper lobe, lobectomy:
Poorly differentiated non-keratinizing squamous cell carcinoma; margins free of tumor (see report).
No tumor seen in two lymph nodes (0/2).
- B. Station 7 lymph nodes, removal:
No tumor is seen in one lymph node (0/1).
- C. Station 9 lymph nodes, removal:
No tumor is seen in five lymph nodes (0/5).
- [REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file aa7dee53-6ea3-4394-8912-faea83a241ee (TCGA-43-7658.0C0D2EB2-AF28-40F9-A4A3-067C1BC78CC6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).